Somatic mutation profile of tumor specimen TCGA-71-6725-01A (aliquot TCGA-71-6725-01A-11D-1855-08) from TCGA case TCGA-71-6725, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 48.7 years (17,793 days).
Specimen TCGA-71-6725-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f79d17cb-b7b3-453e-b4ca-92cd9197db02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-71-6725-10A (Blood Derived Normal), aliquot TCGA-71-6725-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/795d8614-476a-4404-8262-90002c19941c

The open-access MAF lists 60 somatic variants for this specimen: 41 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 16, Intron 3, Nonsense Mutation 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY10 | c.3600G>C p.K1200N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV63241492; called by muse, mutect2, varscan2
- ADGRA1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs761180491, COSV66925940; called by muse, mutect2, varscan2
- AGBL5 | c.1678C>T p.R560* | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV59936819; called by muse, mutect2, varscan2
- BCLAF1 | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 28/293 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs761434446, COSV62143043, COSV62144533; called by muse, mutect2
- CLASP1 | c.3463A>G p.K1155E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.055); catalogued as rs368898801; called by muse, mutect2
- CNOT4 | c.1638T>G p.S546R (on ENST00000541284 / NM_001190850.1; = p.S543R on NM_001190849.2) | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV64158239; called by muse, mutect2
- COL19A1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754662807, COSV59571613; called by muse, mutect2, varscan2
- CRABP2 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV100957542; called by muse, mutect2, varscan2
- DHX30 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs138729543; called by muse, mutect2, varscan2
- DUOX1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 11/317 reads (3%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.055); catalogued as COSV50993849; called by muse, mutect2
- EGFR | c.2239_2251delinsC p.L747_T751delinsP | In Frame Del (DEL) | VAF 56/100 reads (56%) | catalogued as rs397509368, COSV51765856; ClinVar: drug response; called by pindel, varscan2*
- ERAP2 | c.2742G>A p.V914= | Splice Region (SNP) | VAF 26/78 reads (33%) | catalogued as COSV65940086; called by muse, mutect2, varscan2
- F5 | c.3940C>A p.P1314T | Missense Mutation (SNP) | VAF 134/809 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV63125070; called by muse, varscan2
- FAM83C | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs769453860, COSV65583406; called by muse, mutect2, varscan2
- FASN | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs974806991; called by mutect2, varscan2
- GALNT7 | c.725T>C p.I242T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53931163; called by muse, mutect2, varscan2
- GARS1 | c.372G>A p.M124I | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1321224389, COSV66828589; called by muse, mutect2, varscan2
- GPC4 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 32/375 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as COSV63696991, COSV63698295; called by muse, mutect2
- GTF2E2 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs527328234, COSV63478589; called by muse, mutect2, varscan2
- HSD3B1 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52491059, COSV52491915; called by muse, mutect2, varscan2
- LONP1 | c.1625G>T p.R542L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62262071, COSV62262525; called by muse, varscan2
- LYN | c.1070A>G p.Y357C | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV70205861; called by muse, mutect2
- MKRN1 | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.391); catalogued as COSV55437268; called by muse, mutect2, varscan2
- MTREX | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57926819; called by muse, mutect2
- MYH6 | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs182373896; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAV1 | c.1694G>A p.G565D | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV55219214; called by muse, mutect2, varscan2
- NFKB1 | c.538G>C p.A180P (on ENST00000394820 / NM_001382627.1; = p.A181P on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV56957566, COSV56958007; called by muse, mutect2, varscan2
- OR4C16 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 68/272 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.856); catalogued as rs767649281, COSV58942497; called by muse, mutect2, varscan2
- OSMR | c.739A>G p.T247A | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57086378; called by muse, mutect2, varscan2
- PIK3C2B | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65812175; called by mutect2, varscan2
- PITPNM3 | c.2452C>T p.R818W | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1459384243, COSV52593161; called by muse, mutect2, varscan2
- RBM27 | c.2681C>A p.T894K | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV54590881; called by muse, mutect2, varscan2
- SLC12A7 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765560780, COSV53758445; called by muse, mutect2, varscan2
- SNRPN | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV57596832; called by muse, mutect2, varscan2
- SOCS4 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100216091; called by muse, mutect2, varscan2
- TMPRSS6 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.346); catalogued as rs760231250, COSV60979630; called by muse, mutect2, varscan2
- UPF2 | c.3202G>A p.G1068R | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV62661343; called by muse, mutect2, varscan2
- ZNF286A | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67845795; called by muse, mutect2, varscan2
- ZNF506 | c.815T>C p.L272P | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101475616; called by muse, mutect2
- CCDC88A | c.2926dup p.I976Nfs*15 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | called by pindel, varscan2
- TP53 | c.465_499del p.R156Afs*13 | Frame Shift Del (DEL) | VAF 25/56 reads (45%) | called by mutect2, pindel
- AKAP6 | c.5055G>A p.A1685= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as rs377635525; called by muse, mutect2, varscan2
- BCL9L | c.3207A>G p.L1069= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV99418935; called by muse, mutect2, varscan2
- BLCAP | c.120G>A p.R40= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99290014; called by muse, mutect2, varscan2
- CA12 | c.1059C>T p.H353= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as rs778620742, COSV51606361; called by muse, mutect2, varscan2
- CACNA1G | c.5511G>A p.T1837= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs375464264, COSV61730075; called by muse, mutect2, varscan2
- DNAH8 | c.11763C>A p.T3921= | Silent (SNP) | VAF 21/590 reads (4%) | catalogued as COSV59454573; called by muse, mutect2
- IGHV3-48 | c.348G>A p.A116= | Silent (SNP) | VAF 57/381 reads (15%) | catalogued as rs1555530505; called by muse, mutect2, varscan2
- KLHL9 | c.129T>C p.L43= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as COSV100757032; called by muse, mutect2, varscan2
- KLK3 | c.603C>T p.R201= | Silent (SNP) | VAF 51/93 reads (55%) | catalogued as rs370658603; called by muse, mutect2, varscan2
- LTBP2 | c.1536G>A p.P512= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs371191837; called by muse, mutect2
- MKI67 | c.4506C>T p.D1502= | Silent (SNP) | VAF 111/402 reads (28%) | catalogued as COSV64074980; called by muse, mutect2, varscan2
- PCDHB15 | c.237G>T p.L79= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV50994645; called by muse, mutect2, varscan2
- RCC1L | c.684C>T p.F228= | Silent (SNP) | VAF 118/206 reads (57%) | catalogued as COSV101344716; called by muse, mutect2, varscan2
- REN | c.564C>T p.A188= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs777368574, COSV65817925; called by muse, mutect2, varscan2
- SKIL | c.303G>A p.L101= | Silent (SNP) | VAF 63/288 reads (22%) | catalogued as rs776450822, COSV52060327; called by muse, mutect2, varscan2
- VPS13B | c.10809C>T p.L3603= | Silent (SNP) | VAF 70/126 reads (56%) | catalogued as COSV62138900, COSV62145675; called by muse, mutect2, varscan2
- BCAS1 | c.927+2417G>A | Intron (SNP) | VAF 18/189 reads (10%) | catalogued as rs757921049, COSV101006075; called by muse, mutect2, varscan2
- CA10 | c.61+22800G>T | Intron (SNP) | VAF 9/64 reads (14%) | catalogued as COSV53345236, COSV99562179; called by muse, mutect2, varscan2
- RFX3 | c.1968+108C>T | Intron (SNP) | VAF 10/132 reads (8%) | catalogued as COSV100174812; called by muse, mutect2
